Gene-level copy-number profile of tumor specimen 1105196 from CPTAC case C317832, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105196: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 720c9940-04ae-4a6c-ae45-8d3824908aa9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105209 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/c6b92021-3213-4d20-b7a9-8558f54520dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 7,049; copy number 2: 47,622; copy number 3: 4,158; copy number 75: 13; copy number 78: 14.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,785,454–8,344,167, 30 genes (within-gene range 0–1): CAMTA1, AL590128.1, AL512330.1, RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:8,511,795–8,513,021, 2 genes (within-gene range 0–1): AL096855.1, AL096855.2.
- chr9:21,802,636–23,682,662, 24 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:528,907–640,706, 13 genes, copy number 75: AC137894.1, HRAS, LRRC56, LMNTD2, LMNTD2-AS1, RASSF7, MIR210HG, MIR210, PHRF1, IRF7, CDHR5, SCT, DRD4.
- chr11:34,105,617–34,916,379, 14 genes, copy number 78 (within-gene range 2–78): NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP.

Autosomal genes at a single copy (total copy number 1): 4,193. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
